Somatic mutation profile of tumor specimen TCGA-CV-6937-01A (aliquot TCGA-CV-6937-01A-11D-2012-08) from TCGA case TCGA-CV-6937, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 71.6 years (26,156 days).
Specimen TCGA-CV-6937-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31919225-1770-4bc7-ae8a-2d8d6ffa42b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6937-10A (Blood Derived Normal), aliquot TCGA-CV-6937-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9738cff9-e331-445e-8dd6-1d98b484adf5

The open-access MAF lists 123 somatic variants for this specimen: 96 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 24, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 2, Intron 2, In Frame Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.4864C>T p.P1622S | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.164); catalogued as COSV101329891; called by muse, mutect2
- ADAD2 | c.1144G>C p.V382L (on ENST00000315906 / NM_001145400.2; = p.V464L on NM_139174.4) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as COSV51894009, COSV99234984; called by muse, mutect2, varscan2
- ADARB2 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV101186458; called by muse, mutect2, varscan2
- AMACR | c.622C>G p.R208G | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100162769, COSV59461644; called by muse, mutect2
- ANO7 | c.2560G>A p.V854I (on ENST00000274979; = p.V800I on NM_001370694.2) | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.228); catalogued as rs537399613, COSV51475823, COSV99237092; called by muse, mutect2, varscan2
- APLP1 | c.1062C>A p.F354L | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99697413; called by muse, mutect2, varscan2
- ARSF | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.394); catalogued as COSV100839409; called by muse, mutect2
- ASTN1 | c.897C>A p.N299K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.979); catalogued as COSV56080458, COSV99920136; called by muse, mutect2, varscan2
- ATR | c.7118A>T p.E2373V | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100637576; called by muse, mutect2, varscan2
- B3GALT1 | c.448C>A p.H150N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.066); catalogued as COSV100002448; called by muse, mutect2, varscan2
- BOC | c.940C>G p.L314V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.102); catalogued as COSV99847844; called by muse, mutect2, varscan2
- BTBD7 | c.1486A>C p.K496Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100597406; called by muse, mutect2
- C4orf17 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100430682; called by muse, mutect2, varscan2
- CALN1 | c.537T>G p.H179Q (on ENST00000329008 / NM_001017440.3; = p.H221Q on NM_031468.4) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.211); catalogued as COSV100204371; called by muse, mutect2, varscan2
- CALU | c.288G>C p.W96C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99975400; called by muse, mutect2, varscan2
- CCDC74A | c.902A>G p.E301G | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV99723502; called by muse, mutect2
- CDH1 | c.1707C>A p.D569E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876660905, COSV99931054; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP63 | c.1725A>C p.K575N | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); catalogued as COSV100132492; called by muse, mutect2, varscan2
- CFAP70 | c.502C>A p.L168I | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV100160076; called by muse, mutect2, varscan2
- CFAP91 | c.1534-1G>T p.X512_splice | Splice Site (SNP) | VAF 13/95 reads (14%) | catalogued as COSV99846766; called by muse, mutect2, varscan2
- CFHR4 | c.1165C>A p.P389T (on ENST00000367416 / NM_001201551.2; = p.P143T on NM_006684.5) | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs375638682, COSV52229968; called by muse, mutect2, varscan2
- DCAF4 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 46/311 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs141315052; called by muse, mutect2, varscan2
- DDR2 | c.1211G>C p.C404S | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.78); catalogued as rs756728715, COSV100906129, COSV63370522; called by muse, mutect2, varscan2
- DNAJB9 | c.608G>A p.C203Y | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99974343; called by muse, mutect2, varscan2
- DOP1A | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.122); catalogued as COSV99380696; called by muse, mutect2
- DZANK1 | c.1840G>A p.G614R (on ENST00000262547 / NM_001099407.1; = p.G421R on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs758735881, COSV52753599; called by muse, mutect2, varscan2
- EBF1 | c.1253A>T p.H418L | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.062); catalogued as COSV100564996; called by muse, mutect2, varscan2
- EIF5B | c.1168A>C p.K390Q | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV99176744; called by muse, mutect2
- EPHA3 | c.2780A>T p.H927L | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV100341998; called by muse, mutect2
- ERMARD | c.1712G>T p.R571L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100824515; called by muse, mutect2, varscan2
- ESRRG | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100752165; called by muse, mutect2, varscan2
- FAM47C | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100792239; called by muse, mutect2, varscan2
- FRMD6 | c.1601C>G p.P534R (on ENST00000344768 / NM_001267046.2; = p.P526R on NM_152330.4) | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV100655498; called by muse, mutect2, varscan2
- GABRA1 | c.1261C>T p.R421* | Nonsense Mutation (SNP) | VAF 49/225 reads (22%) | catalogued as COSV50115651; called by muse, mutect2, varscan2
- GAS8 | c.842A>C p.D281A | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV99243682; called by muse, mutect2, varscan2
- GIN1 | c.325A>C p.K109Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101204255; called by muse, mutect2
- H4C5 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV100747849, COSV100748102; called by muse, mutect2, varscan2
- HLA-A | c.471G>A p.W157* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100954195; called by muse, mutect2, varscan2
- HTR1A | c.1246A>G p.K416E | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV100108849; called by muse, mutect2, varscan2
- KCNA1 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV66839155; called by muse, mutect2, varscan2
- KCNA6 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | catalogued as COSV99768239; called by muse, mutect2, varscan2
- KCNQ3 | c.2105T>G p.V702G | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.353); catalogued as COSV101195341; called by muse, mutect2
- LRP1B | c.8573T>C p.L2858P | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV101250637; called by muse, mutect2, varscan2
- LRRC15 | c.1597A>G p.T533A | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV100752443; called by muse, mutect2
- LTBP4 | c.3928G>A p.G1310S (on ENST00000308370 / NM_001042544.1; = p.G1273S on NM_003573.2) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs770431331, COSV99180313; called by muse, mutect2, varscan2
- MAP3K4 | c.4318A>G p.I1440V | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1259708325, COSV100814971, COSV100815129; called by muse, mutect2, varscan2
- MRPS30 | c.200A>T p.Q67L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.096); catalogued as COSV101539256; called by muse, mutect2, varscan2
- MST1 | c.2048C>T p.T683I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99610483; called by muse, mutect2, varscan2
- MYEF2 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51047982, COSV51055213; called by muse, mutect2, varscan2
- MYO9B | c.6057A>T p.E2019D | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV99812311; called by muse, mutect2, varscan2
- MYOZ1 | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100831751; called by muse, mutect2, varscan2
- NOD1 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs754320439, COSV56115671; called by muse, mutect2, varscan2
- NOTCH2 | c.6783G>C p.E2261D | Missense Mutation (SNP) | VAF 77/345 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56683773, COSV56684579; called by muse, mutect2, varscan2
- OR1I1 | c.446G>A p.W149* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as rs1477966768, COSV99264707; called by muse, mutect2, varscan2
- OR52E2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.185); catalogued as rs370651935; called by muse, mutect2, varscan2
- OR8J1 | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57319444; called by muse, mutect2, varscan2
- OR8S1 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.305); catalogued as rs773752723, COSV59599393; called by muse, mutect2, varscan2
- PACC1 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs772572594, COSV99800659; called by muse, mutect2, varscan2
- PCDH18 | c.1495C>A p.Q499K | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.209); catalogued as COSV100786941, COSV61272706; called by muse, mutect2, varscan2
- PCDHA13 | c.1991C>T p.T664M | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1554181391, COSV99164889; called by muse, mutect2, varscan2
- PJA2 | c.1007A>G p.H336R | Missense Mutation (SNP) | VAF 53/282 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.337); catalogued as COSV100754263; called by muse, mutect2, varscan2
- PKHD1L1 | c.7554A>G p.I2518M | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV101005128; called by muse, mutect2, varscan2
- PPP1R9A | c.1606G>A p.V536I | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs554730923, COSV56884271; called by muse, mutect2, varscan2
- PRKDC | c.4790T>C p.L1597S | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100038026; called by muse, mutect2, varscan2
- PTCH1 | c.1214A>T p.E405V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV100107240; called by muse, mutect2, varscan2
- RBM27 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV99505573; called by muse, mutect2, varscan2
- RELN | c.2506G>T p.G836* | Nonsense Mutation (SNP) | VAF 8/90 reads (9%) | catalogued as COSV100632022; called by muse, mutect2
- REV3L | c.1682A>G p.H561R | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV100724746; called by muse, mutect2
- RNF19A | c.1474A>G p.T492A | Missense Mutation (SNP) | VAF 116/192 reads (60%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.446); catalogued as COSV100347304; called by muse, mutect2, varscan2
- S100A10 | c.183G>T p.Q61H | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV100916713; called by muse, mutect2, varscan2
- SH3BP4 | c.598T>A p.S200T | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100748962; called by muse, mutect2, varscan2
- SLC1A2 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99553755; called by muse, mutect2, varscan2
- SPAG17 | c.929C>A p.T310K | Missense Mutation (SNP) | VAF 345/395 reads (87%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV100307561; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.537C>G p.I179M | Missense Mutation (SNP) | VAF 8/72 reads (11%) | PolyPhen benign (0.02); catalogued as COSV100081124; called by muse, mutect2, varscan2
- STYXL2 | c.569A>G p.E190G | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99608427; called by muse, mutect2, varscan2
- TCHH | c.3775C>T p.R1259C | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV100914862; called by muse, mutect2, varscan2
- TFAP2E | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs763206780, COSV100951434; called by muse, mutect2, varscan2
- TIPRL | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV100893227, COSV63208192; called by muse, mutect2, varscan2
- TMEM63C | c.2320G>C p.E774Q | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.623); catalogued as rs376169418, COSV100029085; called by muse, mutect2, varscan2
- TP53 | c.617del p.L206Wfs*41 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as COSV52853973; called by mutect2, pindel, varscan2
- TRANK1 | c.3503T>C p.L1168P | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100081042; called by muse, mutect2, varscan2
- TRPV4 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.23); catalogued as rs139300843; ClinVar: uncertain significance; called by muse, varscan2
- TUBB1 | c.219G>A p.M73I | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.61); catalogued as rs751490202, COSV99413855; called by muse, mutect2, varscan2
- TUBGCP6 | c.1930G>A p.V644I | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); catalogued as rs781130101, COSV99954681; ClinVar: uncertain significance; called by mutect2, varscan2
- USP5 | c.1541A>G p.E514G | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.232); catalogued as COSV99978066; called by muse, mutect2, varscan2
- XRCC6 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.209); catalogued as COSV100777773; called by muse, mutect2, varscan2
- ZNF675 | c.218A>C p.E73A | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100704856, COSV63095549; called by muse, mutect2, varscan2
- ZNF677 | c.1517A>C p.K506T | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV61719572, COSV61722379; called by muse, mutect2
- CFAP65 | c.1087_1089del p.K363del | In Frame Del (DEL) | VAF 9/64 reads (14%) | called by mutect2, pindel, varscan2
- CMTR1 | c.907_917del p.K303* | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | called by pindel, varscan2
- ERCC6L2 | c.4625A>G p.N1542S | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCDHB15 | c.978del p.L327Ffs*21 | Frame Shift Del (DEL) | VAF 35/197 reads (18%) | called by mutect2, pindel, varscan2
- TMEM168 | c.1095dup p.A366Cfs*37 | Frame Shift Ins (INS) | VAF 28/181 reads (15%) | called by mutect2, pindel, varscan2
- TNN | c.1225_1234+2del p.X409_splice | Splice Site (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel
- TNXB | c.8051G>T p.R2684L (on ENST00000647633; = p.R2437L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.358); called by muse, mutect2
- ZMYND12 | c.457_460del p.L153Sfs*30 | Frame Shift Del (DEL) | VAF 27/141 reads (19%) | called by mutect2, pindel, varscan2
- ALG2 | c.846G>A p.Q282= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as rs1343796278, COSV99445344; called by muse, mutect2, varscan2
- ANK2 | c.3513G>A p.L1171= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV99999028; called by muse, mutect2, varscan2
- ARHGEF9 | c.444C>A p.I148= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99491260; called by muse, mutect2, varscan2
- BOD1L1 | c.5097A>G p.A1699= | Silent (SNP) | VAF 46/492 reads (9%) | catalogued as rs1334213781, COSV99238167; called by muse, mutect2
- DENND1A | c.594C>T p.L198= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV101010349; called by muse, mutect2, varscan2
- DICER1 | c.3171A>T p.I1057= | Silent (SNP) | VAF 30/210 reads (14%) | catalogued as COSV100601685; called by muse, mutect2, varscan2
- FCRL3 | c.864G>A p.V288= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as COSV63839005; called by muse, mutect2, varscan2
- KATNA1 | c.468A>G p.E156= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100167586; called by muse, mutect2, varscan2
- KCNN2 | c.987C>T p.V329= (on ENST00000264773; = p.V541= on NM_021614.4) | Silent (SNP) | VAF 26/216 reads (12%) | catalogued as COSV99298558; called by muse, mutect2, varscan2
- METTL24 | c.462T>C p.S154= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs756564737, COSV100133102; called by muse, mutect2, varscan2
- OR5AR1 | c.345G>C p.L115= | Silent (SNP) | VAF 34/257 reads (13%) | catalogued as COSV100265532; called by muse, mutect2, varscan2
- PCDHA13 | c.1443C>T p.D481= | Silent (SNP) | VAF 37/182 reads (20%) | catalogued as rs1554179442, COSV56500898; called by muse, mutect2, varscan2
- PCNX1 | c.1755T>A p.G585= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as COSV99453514; called by muse, mutect2, varscan2
- PIGK | c.1179C>T p.F393= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV100892157; called by muse, mutect2, varscan2
- PIGM | c.366C>T p.R122= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100927993; called by muse, mutect2, varscan2
- PIK3R5 | c.777G>A p.A259= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs764903883, COSV52655672; called by muse, mutect2, varscan2
- PTPRT | c.4242T>C p.R1414= | Silent (SNP) | VAF 29/136 reads (21%) | catalogued as COSV100624474; called by muse, mutect2, varscan2
- RBMXL2 | c.951T>C p.D317= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100182020; called by muse, mutect2, varscan2
- TG | c.6678C>T p.D2226= | Silent (SNP) | VAF 79/188 reads (42%) | catalogued as COSV99598300; called by muse, mutect2, varscan2
- TLR8 | c.834A>T p.I278= (on ENST00000218032 / NM_138636.5; = p.I296= on NM_016610.4) | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99486728; called by muse, mutect2, varscan2
- TMEM147 | c.330G>A p.E110= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV99382005; called by muse, mutect2
- TRAF3IP3 | c.1044C>A p.S348= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99159963; called by muse, varscan2
- TRMT44 | c.1960C>T p.L654= | Silent (SNP) | VAF 27/249 reads (11%) | catalogued as COSV101077538; called by muse, mutect2
- UGT2B4 | c.1452C>T p.T484= | Silent (SNP) | VAF 38/214 reads (18%) | catalogued as COSV100522131; called by muse, mutect2, varscan2
- FRMPD2B | n.609C>A | RNA (SNP) | VAF 94/707 reads (13%) | catalogued as rs1174424516; called by muse, mutect2, varscan2
- RPL13A | c.256+44C>T | Intron (SNP) | VAF 14/77 reads (18%) | catalogued as rs1257418332, COSV99201263; called by muse, mutect2, varscan2
- TTN | c.10303+2719C>G | Intron (SNP) | VAF 36/156 reads (23%) | catalogued as COSV100590553; called by muse, mutect2, varscan2
